Somatic mutation profile of tumor specimen TCGA-CX-7086-01A (aliquot TCGA-CX-7086-01A-11D-2078-08) from TCGA case TCGA-CX-7086, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 53.2 years (19,434 days).
Specimen TCGA-CX-7086-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 312394db-2592-4c36-a447-f7342b4f4a8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CX-7086-10D (Blood Derived Normal), aliquot TCGA-CX-7086-10D-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fb7ec70-13d3-4912-a7f6-19bcd0df09db

The open-access MAF lists 248 somatic variants for this specimen: 190 protein-altering or splice-affecting, 53 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 53, Nonsense Mutation 12, Frame Shift Del 5, Frame Shift Ins 4, Splice Site 3, Intron 3, Translation Start Site 1, 5'Flank 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4126G>C p.D1376H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV101329947; called by muse, mutect2
- ABCC9 | c.2932C>A p.P978T | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs376874273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.2931G>A p.M977I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99684729; called by muse, mutect2, varscan2
- AC131160.1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100226097; called by muse, mutect2, varscan2
- ACIN1 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs774882688, COSV99399142; called by muse, mutect2, varscan2
- ACSL4 | c.1200C>G p.F400L (on ENST00000340800 / NM_022977.2; = p.F359L on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100538315; called by muse, mutect2, varscan2
- ACSL5 | c.1240C>A p.R414S (on ENST00000354273; = p.R470S on NM_016234.3) | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV100634493, COSV61128829; called by muse, mutect2, varscan2
- ACTR5 | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99709906; called by muse, mutect2, varscan2
- ADIPOR2 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100840038; called by muse, mutect2, varscan2
- AGO1 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV100940769; called by muse, mutect2, varscan2
- AHCTF1 | c.3871A>G p.T1291A (on ENST00000366508; = p.T1265A on NM_015446.5) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1482758994, COSV100403198; called by muse, mutect2, varscan2
- AKAP13 | c.8100C>G p.F2700L (on ENST00000394518 / NM_007200.5; = p.F2704L on NM_006738.6) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.912); catalogued as COSV100773207; called by muse, mutect2
- ALDH3B1 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99141706; called by muse, mutect2, varscan2
- ALYREF | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.173); catalogued as COSV100485765; called by muse, mutect2, varscan2
- AMY2B | c.360T>A p.N120K | Missense Mutation (SNP) | VAF 147/299 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.066); catalogued as COSV100796200; called by muse, mutect2, varscan2
- ANLN | c.1918G>C p.D640H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV99731961; called by muse, mutect2
- AP5M1 | c.1207C>T p.L403F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753117339, COSV99841069; called by muse, mutect2, varscan2
- ARHGAP18 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100936025; called by muse, mutect2, varscan2
- ASPH | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100727408; called by muse, mutect2, varscan2
- ASTE1 | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV99393646; called by muse, mutect2
- ATRIP | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99603896; called by muse, mutect2, varscan2
- ATXN10 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as COSV53294756; called by muse, mutect2, varscan2
- B4GALNT2 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs201209295, COSV55925419; called by muse, mutect2, varscan2
- BCL11A | c.2002C>T p.P668S (on ENST00000335712 / NM_001365609.1; = p.P702S on NM_018014.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59633168; called by muse, mutect2, varscan2
- BNC1 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 59/105 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766072426, COSV61757106, COSV61758012; called by muse, mutect2, varscan2
- BOC | c.74C>A p.T25K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV99848222; called by muse, mutect2, varscan2
- BRWD1 | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100312958; called by muse, mutect2, varscan2
- BVES | c.377G>C p.G126A | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.11); catalogued as COSV100114695; called by muse, mutect2, varscan2
- C6 | c.2203G>A p.G735S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV99666602; called by muse, mutect2, varscan2
- C6orf58 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.02); catalogued as COSV100314705; called by muse, mutect2, varscan2
- CALCR | c.758T>C p.M253T (on ENST00000649521 / NM_001164737.2; = p.M237T on NM_001742.4) | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100810424; called by muse, mutect2, varscan2
- CARMIL3 | c.2495C>G p.S832* | Nonsense Mutation (SNP) | VAF 31/156 reads (20%) | catalogued as COSV100549305; called by muse, mutect2, varscan2
- CCDC158 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV101187166; called by muse, mutect2, varscan2
- CCDC170 | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV99498176; called by muse, mutect2, varscan2
- CCKBR | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV58100289; called by muse, mutect2, varscan2
- CCNG2 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as rs1472162451, COSV100313064; called by muse, mutect2, varscan2
- CCNG2 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as rs1177343209, COSV100313068; called by muse, mutect2, varscan2
- CD109 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.262); catalogued as COSV54645086, COSV99752762; called by muse, mutect2, varscan2
- CD163 | c.953G>C p.R318P | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.977); catalogued as COSV100775715, COSV63129385; called by muse, mutect2, varscan2
- CDH18 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV99932554; called by muse, mutect2, varscan2
- CEP126 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.105); catalogued as COSV99680678; called by muse, mutect2
- CILP | c.1994G>C p.R665T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99972889; called by muse, mutect2, varscan2
- CLCN7 | c.1937T>A p.V646D | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99246941; called by muse, mutect2
- CNOT1 | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV99799370; called by muse, mutect2, varscan2
- CNTNAP3 | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1427108514, COSV52665237; called by mutect2, varscan2
- COL6A6 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV100649902; called by muse, mutect2, varscan2
- COMMD10 | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99174512; called by muse, mutect2, varscan2
- COMMD8 | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.55); catalogued as COSV101055651; called by muse, mutect2, varscan2
- CPT1C | c.1552G>C p.D518H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as rs199943704, COSV99773272; called by mutect2, varscan2
- CR2 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100889541; called by muse, mutect2, varscan2
- CSMD1 | c.7771C>A p.P2591T (on ENST00000520002; = p.P2590T on NM_033225.6) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV100144585, COSV104408958; called by muse, mutect2, varscan2
- CYLC1 | c.1825C>G p.L609V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV100254136; called by muse, mutect2
- CYP26A1 | c.971A>G p.Q324R | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as rs1481449299, COSV99814594; called by muse, mutect2, varscan2
- DCAF1 | c.3943G>A p.A1315T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.58); catalogued as COSV100244134; called by muse, mutect2, varscan2
- DDX53 | c.624G>C p.L208F | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV100028698; called by muse, mutect2, varscan2
- DMBT1 | c.482C>A p.S161* | Nonsense Mutation (SNP) | VAF 35/127 reads (28%) | catalogued as COSV100352273; called by muse, mutect2, varscan2
- DNM3 | c.2558C>A p.S853* (on ENST00000355305 / NM_001350206.2; = p.S847* on NM_015569.5) | Nonsense Mutation (SNP) | VAF 72/114 reads (63%) | catalogued as COSV100797804; called by muse, mutect2, varscan2
- DPM1 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.308); catalogued as COSV100857684; called by muse, mutect2, varscan2
- DUOX1 | c.4399A>G p.M1467V | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV99334263; called by muse, mutect2, varscan2
- EHBP1L1 | c.2351C>T p.S784L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV99074349; called by muse, mutect2, varscan2
- ENY2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100373718; called by muse, mutect2, varscan2
- ESCO1 | c.859C>G p.Q287E | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs372616592; called by muse, mutect2, varscan2
- FAM135B | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs772363343, COSV99355956, COSV99356344; called by muse, mutect2
- FAM83C | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.067); catalogued as COSV100981521; called by muse, mutect2
- FBXO32 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1159404147, COSV54890561; called by muse, mutect2, varscan2
- FCAR | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs780512814, COSV100628987; called by muse, mutect2, varscan2
- FGF10 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.373); catalogued as COSV52939846, COSV99240155; called by muse, mutect2, varscan2
- FGG | c.904C>A p.L302I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.896); catalogued as COSV100271719, COSV60194432; called by muse, mutect2, varscan2
- GABRB2 | c.871C>A p.H291N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.241); catalogued as COSV99195692; called by muse, mutect2, varscan2
- GIMAP1 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100211964; called by muse, varscan2
- GLI1 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99953732; called by muse, mutect2, varscan2
- GPR142 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100170688; called by muse, mutect2, varscan2
- GPR156 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.124); catalogued as COSV100251158; called by muse, mutect2, varscan2
- GRB10 | c.1629G>T p.Q543H (on ENST00000398812; = p.Q497H on NM_001001549.3) | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100239832, COSV60018036; called by muse, mutect2, varscan2
- GRM1 | c.2693C>T p.P898L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV99264443; called by muse, mutect2
- H3C13 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as COSV100516040; called by muse, varscan2
- HROB | c.1227G>A p.Q409= | Splice Region (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99809134; called by muse, mutect2
- HTR1A | c.612C>A p.F204L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100108954; called by muse, mutect2, varscan2
- HTT | c.7702A>G p.I2568V | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1213951422, COSV100750473; called by muse, mutect2, varscan2
- HUS1 | c.754T>G p.L252V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99346403; called by muse, mutect2, varscan2
- HYAL2 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99222647; called by muse, mutect2, varscan2
- IFIT2 | c.1246C>A p.Q416K | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99259927; called by muse, mutect2, varscan2
- IFNL2 | c.503del p.K168Rfs*23 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs1225989269; called by pindel, varscan2
- IFT80 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV100424455; called by muse, mutect2, varscan2
- IL16 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs780472079, COSV57263126; called by muse, mutect2, varscan2
- IL4R | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs775681273, COSV99404750; called by muse, mutect2, varscan2
- IQGAP3 | c.3507+2C>A p.X1169_splice | Splice Site (SNP) | VAF 33/148 reads (22%) | catalogued as COSV100752081; called by muse, mutect2, varscan2
- KALRN | c.7489C>T p.R2497W (on ENST00000360013 / NM_001024660.4; = p.R800W on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774067123, COSV52265116; called by muse, mutect2, varscan2
- KDM2A | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV101284593; called by muse, mutect2, varscan2
- KMT2E | c.4235C>G p.S1412* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as COSV99995886; called by muse, mutect2, varscan2
- LAMA2 | c.3043G>A p.E1015K | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV101370176; called by muse, mutect2, varscan2
- LCMT1 | c.638T>A p.L213Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101111605; called by muse, varscan2
- LRRC49 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as rs774604496, COSV53016575, COSV99537030; called by muse, mutect2, varscan2
- LRRIQ1 | c.3336G>T p.L1112F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778417753, COSV101279614; called by muse, mutect2
- MAGEL2 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.007); catalogued as rs760209607, COSV58567750; called by muse, mutect2
- MBD5 | c.3598G>A p.E1200K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV101289961, COSV68697903; called by muse, mutect2
- MCF2L | c.3098C>G p.S1033* (on ENST00000375608; = p.S1001* on NM_024979.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99995509; called by muse, mutect2, varscan2
- MDFIC | c.295G>C p.G99R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs548881845, COSV57565046; called by muse, mutect2, varscan2
- MKLN1 | c.1091A>T p.Y364F | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.523); catalogued as COSV100759703; called by muse, mutect2, varscan2
- MROH9 | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768549118, COSV63012788; called by muse, mutect2, varscan2
- MRPS15 | c.636+1G>C p.X212_splice | Splice Site (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100910596; called by muse, mutect2, varscan2
- MUC16 | c.34085C>T p.P11362L | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as COSV67480936; called by muse, mutect2, varscan2
- MUSK | c.1361A>C p.D454A | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51887740; called by muse, mutect2, varscan2
- MYO16 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV99193588; called by muse, mutect2, varscan2
- MYO5C | c.2644G>T p.V882L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV99954195; called by muse, mutect2, varscan2
- NBEA | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.067); catalogued as COSV100077250; called by muse, mutect2
- NCOA5 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV99275259; called by muse, mutect2
- NLRP7 | c.2141T>C p.V714A (on ENST00000340844 / NM_206828.3; = p.V686A on NM_139176.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV60180447; called by muse, mutect2, varscan2
- NPTXR | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.676); catalogued as COSV60727924; called by muse, mutect2, varscan2
- NRDC | c.1404C>G p.F468L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376985644, COSV100703139; called by muse, mutect2, varscan2
- NRXN1 | c.3668A>T p.N1223I | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100639896; called by muse, mutect2, varscan2
- NUAK1 | c.1139C>T p.S380F | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV99776674; called by muse, mutect2, varscan2
- NUDT2 | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100663528; called by muse, mutect2, varscan2
- OLFML2B | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 40/48 reads (83%) | catalogued as COSV99668087; called by muse, mutect2, varscan2
- OR2T12 | c.686C>A p.T229K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs549916777, COSV100527571; called by muse, mutect2, varscan2
- OR4C46 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as COSV60219914; called by muse, mutect2, varscan2
- OR51M1 | c.290T>C p.F97S | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100150152; called by muse, mutect2, varscan2
- OR5F1 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53546780; called by muse, mutect2, varscan2
- OR7A5 | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV100457642; called by muse, mutect2, varscan2
- PAK6 | c.1952A>T p.E651V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99544257; called by muse, mutect2, varscan2
- PES1 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100073004, COSV58828198; called by muse, mutect2, varscan2
- PEX1 | c.3224C>G p.S1075C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771494018, COSV50394497, COSV99951910; called by muse, mutect2, varscan2
- PEX5L | c.1601C>A p.A534E | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99828026; called by muse, mutect2, varscan2
- PEX5L | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99828027; called by muse, mutect2, varscan2
- PIK3C2A | c.3875C>T p.T1292I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99790316; called by muse, mutect2, varscan2
- PIKFYVE | c.3473G>T p.R1158I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV100009968, COSV52237203; called by muse, varscan2
- PIKFYVE | c.3487C>T p.Q1163* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100009972; called by muse, varscan2
- PLCB1 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs372097607, COSV100568917, COSV100569574; called by muse, mutect2, varscan2
- PLXNA4 | c.3084C>G p.I1028M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs747206524, COSV58145639, COSV58150677; called by muse, mutect2, varscan2
- PPFIA1 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99556933; called by muse, mutect2
- PPFIA4 | c.1975G>A p.D659N (on ENST00000447715; = p.D660N on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV99690301; called by muse, mutect2, varscan2
- PRH1 | c.368C>G p.P123R | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs368972037, COSV70372279; called by muse, varscan2
- PRKCG | c.387G>C p.M129I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV54730220, COSV99668594; called by muse, mutect2
- PRRC2A | c.2380G>C p.D794H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101051035; called by muse, mutect2, varscan2
- PTF1A | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV100919567; called by muse, mutect2
- RAPGEF3 | c.988G>A p.D330N (on ENST00000389212; = p.D288N on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs201965876, COSV99405880, COSV99406300; called by muse, mutect2, varscan2
- REN | c.1059+1G>T p.X353_splice | Splice Site (SNP) | VAF 12/18 reads (67%) | catalogued as COSV99689419; called by muse, mutect2, varscan2
- RFX6 | c.1915C>A p.H639N | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV60589254, COSV60589889; called by muse, mutect2, varscan2
- RIPOR1 | c.637A>G p.M213V (on ENST00000379312 / NM_001193522.2; = p.M209V on NM_024519.4) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99242623; called by muse, mutect2, varscan2
- RP1 | c.6081T>A p.D2027E | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99606431; called by muse, mutect2, varscan2
- RYR3 | c.3305G>A p.G1102D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293256392, COSV101212084; called by muse, mutect2, varscan2
- SACS | c.184A>T p.I62F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.202); catalogued as COSV101207217; called by muse, mutect2, varscan2
- SCARB2 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.733); catalogued as rs763291527, COSV99357822; called by muse, mutect2, varscan2
- SEMA5B | c.3095T>A p.F1032Y | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV99530946; called by muse, mutect2
- SERPINC1 | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV100875006; called by muse, mutect2, varscan2
- SLC10A4 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV99906782; called by muse, mutect2, varscan2
- SLC24A2 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99645911; called by muse, mutect2, varscan2
- SLCO4C1 | c.2053T>C p.F685L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100194579; called by muse, mutect2, varscan2
- SNRNP48 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs926205946, COSV60938731; called by muse, mutect2, varscan2
- SPTBN1 | c.3634G>C p.E1212Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.612); catalogued as COSV100441929; called by muse, mutect2, varscan2
- STIM2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs973703044, COSV52841257; called by muse, mutect2, varscan2
- SUPT5H | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs772570773, COSV100781930; called by muse, mutect2, varscan2
- SYNE2 | c.14209G>A p.E4737K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV100646860; called by muse, mutect2, varscan2
- TAB2 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV99644563; called by muse, mutect2, varscan2
- TACR3 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as COSV100510148; called by muse, mutect2, varscan2
- TBC1D8B | c.2273A>G p.Y758C | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99343938; called by muse, mutect2, varscan2
- TGS1 | c.2141G>C p.R714T | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV99485117; called by muse, mutect2, varscan2
- TIGD4 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV58550153; called by muse, mutect2, varscan2
- TLR4 | c.1511C>G p.S504C (on ENST00000355622 / NM_138554.5; = p.S464C on NM_003266.4) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100842677; called by muse, mutect2, varscan2
- TMPRSS11E | c.985C>T p.L329F | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100542245; called by muse, mutect2, varscan2
- TMTC1 | c.1690A>C p.K564Q (on ENST00000539277 / NM_001193451.2; = p.K456Q on NM_175861.3) | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.116); catalogued as COSV99758893; called by muse, mutect2, varscan2
- TOX3 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV54873617; called by muse, mutect2, varscan2
- TP53 | c.876del p.E294Sfs*51 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | catalogued as COSV52795860, COSV53037721, COSV53188887; called by mutect2, pindel, varscan2
- TREML1 | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100914272, COSV64191036; called by muse, mutect2, varscan2
- TRMT5 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV99711944; called by muse, mutect2
- TSSK2 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs374546658; called by muse, mutect2, varscan2
- TTC7B | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100127452; called by muse, mutect2, varscan2
- TTN | c.14987A>T p.N4996I (on ENST00000591111; = p.N4069I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | PolyPhen possibly damaging (0.885); catalogued as COSV100597279; called by muse, mutect2, varscan2
- UBR1 | c.1397A>T p.Q466L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV99316717; called by muse, mutect2, varscan2
- UTP20 | c.973A>G p.T325A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99880904; called by muse, mutect2, varscan2
- VPS13C | c.3670A>G p.R1224G (on ENST00000644861 / NM_020821.3; = p.R1181G on NM_017684.5) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV99827464; called by muse, mutect2, varscan2
- VPS8 | c.712A>G p.T238A (on ENST00000625842 / NM_001349294.1; = p.T236A on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as rs755685702, COSV99800939; called by muse, mutect2, varscan2
- XKR4 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs145363139; called by muse, mutect2, varscan2
- ZC3H13 | c.1165C>G p.P389A | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV99667577; called by muse, mutect2, varscan2
- ZEB1 | c.707G>T p.C236F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV100313759; called by muse, mutect2, varscan2
- ZNF251 | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs906609598, COSV99478175; called by muse, mutect2, varscan2
- ZNF324B | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1315815414, COSV100351538; called by muse, mutect2, varscan2
- ZNF462 | c.6496A>T p.R2166W | Missense Mutation (SNP) | VAF 50/66 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99470917; called by muse, mutect2, varscan2
- ZNF596 | c.817C>A p.H273N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100261528; called by muse, mutect2, varscan2
- ZNF701 | c.1424G>C p.R475P (on ENST00000301093; = p.R409P on NM_018260.3) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs917778892, COSV56523231; called by muse, varscan2
- ZNF83 | c.1353C>A p.H451Q | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99991192; called by muse, mutect2, varscan2
- ARSA | c.1424_1445del p.G475Afs*38 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- FGF21 | c.284del p.G95Efs*100 | Frame Shift Del (DEL) | VAF 26/151 reads (17%) | called by mutect2, pindel, varscan2
- IAH1 | c.551dup p.M184Ifs*23 | Frame Shift Ins (INS) | VAF 21/62 reads (34%) | called by mutect2, pindel, varscan2
- MARS1 | c.1451C>G p.S484C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- NBPF11 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PDZD2 | c.5890_5891insGTTC p.L1964Rfs*14 | Frame Shift Ins (INS) | VAF 28/107 reads (26%) | called by mutect2, pindel, varscan2
- PRPH2 | c.872dup p.D291Efs*10 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- SPTBN2 | c.4869_4888del p.Q1624Pfs*26 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- ZNF436 | c.738_739dup p.E247Vfs*20 | Frame Shift Ins (INS) | VAF 30/85 reads (35%) | called by mutect2, pindel, varscan2
- ALCAM | c.816G>A p.G272= | Silent (SNP) | VAF 25/147 reads (17%) | catalogued as rs1470258788, COSV100064332; called by muse, mutect2, varscan2
- ANKRD35 | c.2742G>A p.E914= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100841644; called by muse, mutect2, varscan2
- APH1A | c.54C>T p.F18= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs782165938, COSV52528202; called by muse, mutect2, varscan2
- ARHGAP18 | c.732A>G p.K244= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV100936024; called by muse, mutect2, varscan2
- ATXN2L | c.3021G>A p.Q1007= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV100293785; called by muse, mutect2, varscan2
- BCL9 | c.1356C>T p.S452= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99324557; called by muse, mutect2, varscan2
- BNC2 | c.2694C>T p.D898= | Silent (SNP) | VAF 42/57 reads (74%) | catalogued as rs764158622, COSV101035438; called by muse, mutect2, varscan2
- BRD4 | c.3300C>T p.S1100= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs778881856, COSV99650007; called by muse, mutect2, varscan2
- C3AR1 | c.900T>A p.A300= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV99368159; called by muse, mutect2, varscan2
- CACHD1 | c.183G>A p.G61= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV99261558; called by muse, mutect2, varscan2
- CASR | c.2826G>A p.G942= (on ENST00000490131; = p.G1019= on NM_000388.4) | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs1396410957, COSV99948528; called by muse, mutect2, varscan2
- CCDC181 | c.1529G>A p.*510= (on ENST00000367806 / NM_001300969.1; = p.*509= on NM_021179.2) | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100250508; called by muse, mutect2, varscan2
- COL14A1 | c.1443G>A p.E481= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99918215; called by muse, mutect2, varscan2
- COL14A1 | c.3552C>T p.P1184= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV99918217; called by muse, mutect2
- CYLC1 | c.954G>A p.K318= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as COSV100254134; called by muse, mutect2, varscan2
- DIRAS2 | c.165C>T p.C55= | Silent (SNP) | VAF 75/98 reads (77%) | catalogued as rs761318867, COSV101005817; called by muse, mutect2, varscan2
- DNAH8 | c.4752C>T p.F1584= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100543567, COSV59434706; called by muse, mutect2, varscan2
- EFCAB5 | c.585G>A p.K195= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- EMB | c.402C>T p.S134= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1433670309, COSV100296630; called by muse, mutect2, varscan2
- EPPK1 | c.1039C>T p.L347= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as COSV101599750, COSV73262258; called by muse, mutect2, varscan2
- FARP2 | c.2197C>T p.L733= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1471024782, COSV99884029; called by muse, mutect2, varscan2
- FCGR2A | c.840C>T p.D280= (on ENST00000271450 / NM_001136219.3; = p.D279= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV54840991, COSV99615039; called by muse, mutect2, varscan2
- FSIP2 | c.18399T>C p.Y6133= | Silent (SNP) | VAF 5/108 reads (5%) | catalogued as COSV100554213; called by muse, mutect2
- GABRB2 | c.870C>T p.T290= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV99195694; called by muse, mutect2, varscan2
- GRAMD1A | c.2109C>T p.H703= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99386491; called by muse, mutect2, varscan2
- HSF4 | c.1470C>T p.P490= (on ENST00000521374 / NM_001040667.3; = p.P460= on NM_001538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99220403; called by muse, mutect2, varscan2
- IFT74 | c.1587A>G p.L529= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV101197128; called by muse, mutect2, varscan2
- ING3 | c.12A>G p.L4= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs1396073949, COSV100187328; called by muse, mutect2, varscan2
- LPIN1 | c.402C>T p.S134= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV99877113; called by muse, mutect2
- LRRC66 | c.1713T>C p.Y571= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as rs1310670149, COSV100602841; called by muse, mutect2, varscan2
- LTBP3 | c.2961C>T p.G987= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99533825; called by muse, mutect2, varscan2
- MARCHF11 | c.633C>A p.T211= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100197474; called by muse, mutect2, varscan2
- MCHR1 | c.441C>A p.P147= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV99967745; called by muse, mutect2, varscan2
- MLC1 | c.1133G>A p.*378= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100286250; called by muse, mutect2, varscan2
- MUC16 | c.32307C>T p.V10769= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV101198395; called by muse, mutect2, varscan2
- NASP | c.1242C>G p.V414= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100601648; called by muse, mutect2, varscan2
- NTN3 | c.633C>G p.L211= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99564713; called by muse, mutect2, varscan2
- NUAK2 | c.1563C>T p.F521= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs565958619, COSV100903979; called by muse, mutect2, varscan2
- PHRF1 | c.1788G>A p.A596= (on ENST00000264555 / NM_001286581.2; = p.A595= on NM_020901.4) | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs772093175, COSV99199592; called by muse, mutect2, varscan2
- PLEC | c.12873G>C p.V4291= (on ENST00000322810 / NM_201380.4; = p.V4181= on NM_000445.5) | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV100511477; called by muse, mutect2
- PPFIA1 | c.1026C>G p.L342= | Silent (SNP) | VAF 13/324 reads (4%) | catalogued as COSV99556934; called by muse, mutect2
- RADIL | c.1482C>T p.C494= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs758378494, COSV68200107; called by muse, mutect2, varscan2
- RELB | c.1674C>T p.F558= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV55510332; called by muse, mutect2, varscan2
- SEL1L2 | c.1809C>T p.G603= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs1439872602, COSV99532689; called by muse, mutect2, varscan2
- SF3B3 | c.1143A>G p.E381= | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as COSV100209614; called by muse, mutect2, varscan2
- SPATC1 | c.1368G>A p.R456= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV101084757; called by muse, mutect2, varscan2
- SSH2 | c.1998C>T p.T666= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as rs763751587, COSV99281517; called by muse, mutect2, varscan2
- STXBP5L | c.2034C>T p.T678= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as rs768379475, COSV56519752, COSV99872360; called by muse, mutect2, varscan2
- TOMM40 | c.315C>A p.V105= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV99374795; called by muse, mutect2
- TONSL | c.1791A>G p.E597= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as COSV101340148; called by muse, mutect2, varscan2
- UNC93A | c.1341G>A p.Q447= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV100023098; called by muse, mutect2, varscan2
- URB2 | c.606C>T p.L202= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV99270717; called by muse, mutect2, varscan2
- ZNF605 | c.504C>G p.V168= | Silent (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- ABCC5 | c.592-2355G>A | Intron (SNP) | VAF 18/163 reads (11%) | catalogued as COSV99656505; called by muse, mutect2, varscan2
- ALG11 | c.-1G>A | 5'UTR (SNP) | VAF 13/40 reads (33%) | catalogued as COSV54444474; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498988 T>A | 5'Flank (SNP) | VAF 49/86 reads (57%) | called by muse, mutect2, varscan2
- MGAM | c.4618+1924C>T | Intron (SNP) | VAF 6/45 reads (13%) | catalogued as rs775847583, COSV101527390; called by muse, mutect2, varscan2
- TIAL1 | c.130-31C>G | Intron (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100958336, COSV100958349; called by muse, mutect2, varscan2
